Somatic mutation profile of tumor specimen TCGA-G4-6321-01A (aliquot TCGA-G4-6321-01A-11D-1719-10) from TCGA case TCGA-G4-6321, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage III; Age at diagnosis: 60.0 years (21,921 days).
Specimen TCGA-G4-6321-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8b9849f-c4be-4c23-8a6c-8a2f394ca52c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6321-10A (Blood Derived Normal), aliquot TCGA-G4-6321-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e94e8046-8749-49f5-942b-5a620468feb7

The open-access MAF lists 64 somatic variants for this specimen: 53 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 47, Silent 11, Nonsense Mutation 4, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACTR8 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1000438448, COSV51635578; called by muse, mutect2, varscan2
- ADH7 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs768043074, COSV52923459; called by muse, varscan2
- AHNAK2 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 36/564 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as rs368803269; called by muse, mutect2
- ARHGAP21 | c.3814G>T p.E1272* | Nonsense Mutation (SNP) | VAF 166/908 reads (18%) | catalogued as COSV57602587; called by muse, mutect2, varscan2
- AVPR1B | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as rs1287040763, COSV100899374; called by muse, mutect2, varscan2
- BPIFB1 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs199854129, COSV53606550; called by muse, mutect2, varscan2
- CACNA1E | c.5701C>T p.R1901C | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs199591744, COSV62394080; called by muse, mutect2, varscan2
- CFAP61 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV55618341; called by muse, mutect2, varscan2
- CHL1 | c.3446G>A p.R1149Q (on ENST00000397491 / NM_001253387.1; = p.R1165Q on NM_006614.4) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as rs139892128, COSV99852503; called by muse, mutect2, varscan2
- CLEC11A | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); catalogued as COSV51575074; called by muse, mutect2
- COL16A1 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54705511; called by muse, mutect2, varscan2
- CPXM2 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368914654; called by muse, mutect2, varscan2
- CTNNA3 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV100373602; called by muse, mutect2
- DOCK3 | c.3331C>T p.R1111W | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774398189, COSV56509467; called by muse, mutect2, varscan2
- DSG3 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV57128696; called by muse, mutect2
- ELAVL2 | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.138); catalogued as COSV99806243; called by muse, mutect2
- EYA4 | c.720G>T p.M240I | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV62051699; called by muse, mutect2, varscan2
- FASTKD1 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV71624309; called by muse, mutect2, varscan2
- FAT4 | c.5612G>C p.G1871A | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100628645, COSV58690796; called by muse, mutect2, varscan2
- FBN2 | c.4649C>T p.T1550M | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1174261486, COSV52512408; called by muse, mutect2, varscan2
- GABRA3 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100943100, COSV64795024; called by muse, mutect2
- GALM | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs990325550, COSV55370488; called by muse, mutect2
- GAS6 | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs767144171, COSV59849902; called by muse, mutect2, varscan2
- GK | c.1527G>T p.W509C (on ENST00000427190 / NM_001205019.2; = p.W503C on NM_000167.6) | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66732297; called by muse, mutect2
- HNRNPL | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.958); catalogued as COSV55492548; called by muse, mutect2
- IRX1 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57359430; called by muse, mutect2
- LAMA4 | c.1540C>T p.R514W (on ENST00000230538 / NM_001105206.3; = p.R507W on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs782767592, COSV57896200; called by muse, mutect2, varscan2
- LAMA5 | c.1214G>T p.C405F | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53373235, COSV99440109; called by muse, mutect2
- LAS1L | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV56707255; called by muse, mutect2
- LRP1B | c.13396C>A p.L4466I | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV67211861; called by muse, mutect2
- MAGEB4 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66775912; called by muse, mutect2
- MUC16 | c.39386C>T p.T13129I | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.912); catalogued as COSV66691898; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | catalogued as rs747914168; called by mutect2, varscan2
- NLGN3 | c.1549G>T p.A517S (on ENST00000358741 / NM_181303.2; = p.A497S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as COSV62443195; called by muse, mutect2
- OR52B2 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV73209366; called by muse, mutect2, varscan2
- PCDHGA9 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.235); catalogued as rs761887627, COSV53926626; called by muse, mutect2, varscan2
- PDP2 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1482446700, COSV61240063; called by muse, mutect2
- PURA | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100495737; called by muse, mutect2
- RADX | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs370255784, COSV65318555; called by muse, mutect2, varscan2
- SLC10A4 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56718725; called by muse, mutect2
- SLC2A9 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370374119, COSV53320451; called by muse, mutect2, varscan2
- SLC51A | c.633C>T p.D211= | Splice Region (SNP) | VAF 19/148 reads (13%) | catalogued as rs772271053, COSV56351138; called by muse, mutect2, varscan2
- SYT16 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs201294056, COSV70856512; called by muse, mutect2
- TAF7L | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 62/217 reads (29%) | catalogued as COSV61257030, COSV61257807; called by muse, mutect2, varscan2
- TMEM132D | c.3254G>T p.C1085F | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV67160325, COSV67160978; called by muse, mutect2, varscan2
- TMPRSS11A | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs757090282, COSV58357045; called by muse, mutect2
- TRPS1 | c.113C>T p.S38F (on ENST00000220888 / NM_001330599.2; = p.S51F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs375022768; called by muse, mutect2, varscan2
- VAV3 | c.1974C>A p.C658* | Nonsense Mutation (SNP) | VAF 76/355 reads (21%) | catalogued as COSV58382339; called by muse, mutect2, varscan2
- ZDHHC4 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as rs372891853; called by muse, mutect2, varscan2
- ZFHX4 | c.6278C>A p.P2093H | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV50541754, COSV51000797; called by muse, mutect2
- NCBP1 | c.1523T>C p.F508S | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- USF3 | c.3499G>A p.A1167T | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- ANK2 | c.6C>A p.T2= | Silent (SNP) | VAF 46/690 reads (7%) | catalogued as COSV101541472; called by muse, mutect2
- ARHGEF5 | c.4551C>T p.C1517= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as COSV50210228; called by muse, mutect2, varscan2
- CGB5 | c.360C>T p.C120= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as COSV100032029; called by muse, mutect2, varscan2
- GRB7 | c.870C>T p.R290= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV58447900; called by muse, mutect2, varscan2
- GRK7 | c.1368G>A p.T456= | Silent (SNP) | VAF 48/238 reads (20%) | catalogued as rs762291728, COSV53821530; called by muse, mutect2, varscan2
- KIF26B | c.2910G>A p.G970= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV63641356; called by muse, mutect2
- PCDHGA6 | c.2199G>A p.A733= | Silent (SNP) | VAF 72/378 reads (19%) | catalogued as COSV53945331; called by muse, mutect2, varscan2
- POU6F1 | c.1617C>T p.G539= | Silent (SNP) | VAF 36/345 reads (10%) | catalogued as rs755891944, COSV100374814; called by muse, mutect2, varscan2
- SAGE1 | c.942C>T p.N314= | Silent (SNP) | VAF 30/328 reads (9%) | catalogued as rs782749871, COSV61013316; called by muse, mutect2
- SALL1 | c.1005C>T p.S335= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs972073520, COSV51757228; called by muse, mutect2, varscan2
- TBX15 | c.1395C>T p.Y465= (on ENST00000369429 / NM_001330677.2; = p.Y359= on NM_152380.3) | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as rs1302976111, COSV52871029; called by muse, mutect2
